Somatic mutation profile of tumor specimen TARGET-30-PANUIF-01A (aliquot TARGET-30-PANUIF-01A-01D) from TARGET case TARGET-30-PANUIF, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 6.1 years (2,234 days).
Specimen TARGET-30-PANUIF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8c81cf1a-314b-4d9b-90e1-aed76bce122d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PANUIF-10A (Blood Derived Normal), aliquot TARGET-30-PANUIF-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7d30ad20-ba6f-4680-8561-eee0cb875af4

The open-access MAF lists 95 somatic variants for this specimen: 77 protein-altering or splice-affecting, 16 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 70, Silent 16, Nonsense Mutation 4, RNA 2, Frame Shift Del 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A2M | c.2612C>A p.T871N | Missense Mutation (SNP) | VAF 32/173 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.558); catalogued as COSV59384587; called by muse, mutect2, varscan2
- A2M | c.2188A>T p.T730S | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.196); catalogued as COSV59384600; called by muse, mutect2, varscan2
- ABCA4 | c.2707G>C p.E903Q | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.017); catalogued as COSV64672476; called by muse, mutect2, varscan2
- ACCSL | c.1530C>G p.N510K | Missense Mutation (SNP) | VAF 52/149 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.034); catalogued as COSV66580746; called by muse, mutect2, varscan2
- ADAM30 | c.900A>T p.K300N | Missense Mutation (SNP) | VAF 165/765 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV65560693; called by muse, mutect2, varscan2
- AMER1 | c.1103G>A p.G368D | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57657731; called by muse, mutect2, varscan2
- ATP10B | c.3206G>A p.G1069E | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59147541; called by muse, mutect2, varscan2
- BAIAP3 | c.3353C>T p.A1118V | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs564941772, COSV50103807; called by muse, mutect2, varscan2
- CDH10 | c.1174G>T p.E392* | Nonsense Mutation (SNP) | VAF 10/61 reads (16%) | catalogued as COSV52576048; called by muse, mutect2, varscan2
- CNTF | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.749); catalogued as COSV60158162; called by muse, mutect2, varscan2
- CPS1 | c.2173C>A p.L725M | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD114408, COSV51806170; called by muse, mutect2, varscan2
- CUL3 | c.18A>T p.K6N | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV52363056; called by muse, mutect2
- DHDH | c.424G>T p.G142* | Nonsense Mutation (SNP) | VAF 46/109 reads (42%) | catalogued as COSV55481837; called by muse, mutect2, varscan2
- DNAH1 | c.579G>T p.E193D | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.587); catalogued as COSV70227599; called by mutect2, varscan2
- EPHA2 | c.2563C>A p.Q855K | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.148); catalogued as COSV64452568; called by muse, mutect2, varscan2
- FCRL6 | c.413C>T p.P138L | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as rs756692036, COSV58940417; called by muse, mutect2, varscan2
- FGFBP2 | c.233C>A p.P78H | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52587787; called by muse, mutect2, varscan2
- GAPDHS | c.685T>A p.L229M | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV55880211; called by muse, mutect2, varscan2
- GLIS1 | c.926G>A p.R309H | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1003795975, COSV56546494; called by muse, mutect2, varscan2
- GTF3C4 | c.1758G>C p.Q586H | Missense Mutation (SNP) | VAF 50/293 reads (17%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.896); catalogued as COSV64645128; called by muse, mutect2, varscan2
- GUCY2D | c.2827C>T p.Q943* | Nonsense Mutation (SNP) | VAF 21/73 reads (29%) | catalogued as COSV54695468; called by muse, mutect2, varscan2
- HCFC2 | c.1955G>A p.R652K | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV57558275; called by muse, varscan2
- IKZF1 | c.473G>T p.G158V | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58783716, COSV58793079; called by muse, mutect2, varscan2
- INPP5D | c.1192C>A p.Q398K (on ENST00000445964 / NM_001017915.3; = p.Q397K on NM_005541.5) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.031); catalogued as rs867948305, COSV64036276; called by muse, mutect2, varscan2
- KNTC1 | c.4254T>G p.F1418L | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.519); catalogued as COSV100338703, COSV61079446; called by muse, mutect2, varscan2
- LILRA5 | c.481C>A p.Q161K | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.145); catalogued as COSV100006784, COSV56642105; called by muse, mutect2, varscan2
- MPP7 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.015); catalogued as COSV61731285; called by muse, mutect2, varscan2
- MRTFB | c.1378G>T p.E460* | Nonsense Mutation (SNP) | VAF 18/106 reads (17%) | catalogued as COSV57956952; called by muse, mutect2, varscan2
- MUC16 | c.25054G>T p.A8352S | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.047); catalogued as COSV67455976, COSV67489604; called by muse, mutect2, varscan2
- MYBPC1 | c.1346A>T p.E449V (on ENST00000550270 / NM_206820.2; = p.E474V on NM_002465.4) | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV62252050, COSV62253297; called by muse, mutect2, varscan2
- MYO3B | c.1609A>T p.I537F | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); catalogued as COSV58699257; called by muse, mutect2, varscan2
- OPA1 | c.526C>T p.L176F | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV62479734; called by muse, mutect2, varscan2
- OR52D1 | c.676C>A p.H226N | Missense Mutation (SNP) | VAF 39/194 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.122); catalogued as COSV59487243; called by muse, mutect2, varscan2
- OR5B21 | c.811G>C p.A271P | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.945); catalogued as COSV64481723; called by muse, mutect2, varscan2
- PCBP4 | c.362G>T p.G121V | Missense Mutation (SNP) | VAF 38/47 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59054127; called by muse, varscan2
- PEBP1 | c.314A>C p.D105A | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.009); catalogued as COSV54336939; called by muse, mutect2, varscan2
- PMFBP1 | c.1996G>C p.E666Q (on ENST00000537465; = p.E661Q on NM_031293.3) | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.846); catalogued as COSV52822280; called by muse, mutect2, varscan2
- PRLR | c.1785C>A p.F595L | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.6); PolyPhen benign (0.112); catalogued as COSV51494415; called by muse, mutect2, varscan2
- PRRC1 | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.997); catalogued as COSV56988684; called by muse, mutect2, varscan2
- PTF1A | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV64734928; called by muse, mutect2, varscan2
- PTPN3 | c.1436A>G p.D479G | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.056); catalogued as rs759626144, COSV52704391; called by muse, mutect2, varscan2
- PTPRS | c.4975C>T p.R1659C | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1314953096; called by muse, mutect2
- RASGRF1 | c.1608C>T p.A536= | Splice Region (SNP) | VAF 24/73 reads (33%) | catalogued as COSV69177810; called by muse, mutect2, varscan2
- SLC35G1 | c.895C>A p.Q299K (on ENST00000427197 / NM_001134658.3; = p.Q298K on NM_153226.4) | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65055084; called by muse, mutect2, varscan2
- SLFN11 | c.970G>A p.V324M | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57698183; called by muse, mutect2, varscan2
- STX3 | c.334G>C p.D112H | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV55696582; called by muse, mutect2, varscan2
- SUGP2 | c.1363A>C p.K455Q | Missense Mutation (SNP) | VAF 87/214 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58256855; called by muse, mutect2, varscan2
- TKTL1 | c.753G>T p.Q251H | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.063); catalogued as COSV54212342; called by muse, mutect2, varscan2
- TNFAIP2 | c.1775C>T p.A592V | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60694181; called by mutect2, varscan2
- TNXB | c.6812G>C p.G2271A (on ENST00000647633; = p.G2024A on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 209/525 reads (40%) | SIFT tolerated (0.85); PolyPhen probably damaging (0.97); catalogued as COSV64476229; called by muse, mutect2, varscan2
- ZNF14 | c.459C>A p.H153Q | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV59848932; called by muse, mutect2, varscan2
- ZNF658 | c.43G>A p.V15M | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as rs1251199772; called by muse, mutect2, varscan2
- ZNF789 | c.662G>T p.R221I | Missense Mutation (SNP) | VAF 24/198 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as rs147857503; called by muse, mutect2, varscan2
- ABI3 | c.329G>A p.G110D | Missense Mutation (SNP) | VAF 15/181 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ATXN2 | c.3793C>A p.P1265T (on ENST00000550104; = p.P1105T on NM_002973.4) | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- BAZ1A | c.1765C>A p.L589I | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CDH1 | c.1300G>A p.G434S | Missense Mutation (SNP) | VAF 33/257 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CPNE2 | c.992A>C p.N331T | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- EPS15L1 | c.951G>T p.W317C | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FCGBP | c.5735G>C p.G1912A | Missense Mutation (SNP) | VAF 14/342 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.718); called by muse, mutect2
- FGF10 | c.449G>C p.C150S | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FOXD4L3 | c.802C>A p.L268I | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.036); called by mutect2, varscan2
- ICE2 | c.2654C>A p.A885E | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- IGLV1-50 | c.119C>A p.S40Y | Missense Mutation (SNP) | VAF 235/407 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- IL12RB2 | c.386A>C p.N129T | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); called by muse, mutect2
- IQGAP2 | c.4329C>A p.D1443E | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.16); called by muse, mutect2
- POLR3A | c.3895_3901del p.E1299Wfs*11 | Frame Shift Del (DEL) | VAF 10/39 reads (26%) | called by mutect2, pindel, varscan2
- RELN | c.2621C>T p.T874I | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); called by muse, mutect2
- SLC1A4 | c.883G>C p.G295R | Missense Mutation (SNP) | VAF 28/190 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC4A1 | c.1259C>A p.A420D | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2
- SMS | c.751G>T p.V251F | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SOX7 | c.885C>G p.N295K | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.69); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- TGM1 | c.209del p.G70Vfs*41 | Frame Shift Del (DEL) | VAF 22/157 reads (14%) | called by mutect2, pindel, varscan2
- TRAV2 | c.15C>A p.S5R | Missense Mutation (SNP) | VAF 39/287 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- TRAV34 | c.256G>T p.D86Y | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- WWTR1 | c.419G>T p.R140M | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.608); called by mutect2, varscan2
- ZHX1 | c.840A>C p.L280F | Missense Mutation (SNP) | VAF 35/256 reads (14%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BTBD10 | c.232A>C p.R78= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as COSV53398437; called by muse, mutect2, varscan2
- ENPP2 | c.2382C>T p.F794= (on ENST00000075322 / NM_001040092.3; = p.F846= on NM_006209.5) | Silent (SNP) | VAF 32/86 reads (37%) | catalogued as COSV50011938; called by muse, mutect2, varscan2
- FAM193B | c.1959C>G p.P653= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV100286598, COSV61557608; called by muse, mutect2, varscan2
- LTF | c.630C>T p.S210= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as rs1249321288, COSV51606832; called by muse, mutect2, varscan2
- MATN4 | c.171C>T p.L57= | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as COSV59213129; called by muse, mutect2, varscan2
- MMP1 | c.345C>A p.T115= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as COSV59509996; called by muse, mutect2, varscan2
- NRL | c.295C>T p.L99= | Silent (SNP) | VAF 19/110 reads (17%) | catalogued as COSV53743367; called by muse, mutect2, varscan2
- PLAG1 | c.1371C>A p.P457= | Silent (SNP) | VAF 35/185 reads (19%) | catalogued as COSV57610248; called by muse, mutect2, varscan2
- PLCE1 | c.5535G>T p.L1845= | Silent (SNP) | VAF 15/134 reads (11%) | called by muse, mutect2, varscan2
- PMFBP1 | c.2910G>A p.T970= (on ENST00000537465; = p.T965= on NM_031293.3) | Silent (SNP) | VAF 11/69 reads (16%) | catalogued as rs78521983; called by muse, mutect2, varscan2
- SIGLEC12 | c.1299G>A p.L433= (on ENST00000291707 / NM_053003.4; = p.L315= on NM_033329.2) | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as COSV52460539, COSV99389115; called by muse, mutect2, varscan2
- SLC18A2 | c.1401C>T p.C467= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as rs887210501, COSV53692700; called by muse, mutect2, varscan2
- TNXB | c.1254C>T p.R418= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as COSV64476241; called by muse, mutect2, varscan2
- TPH1 | c.1116C>T p.V372= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV51457545; called by muse, mutect2, varscan2
- ZNF180 | c.240C>T p.D80= | Silent (SNP) | VAF 48/100 reads (48%) | catalogued as rs770437525, COSV55420425; called by muse, mutect2, varscan2
- ZNF257 | c.906C>A p.T302= | Silent (SNP) | VAF 5/56 reads (9%) | called by muse, mutect2
- HLA-DRB9 | n.190G>A | RNA (SNP) | VAF 26/146 reads (18%) | catalogued as rs769848815; called by muse, mutect2
- SSPOP | n.5792C>T | RNA (SNP) | VAF 84/160 reads (53%) | catalogued as rs776382320, COSV50486988; called by muse, mutect2, varscan2
